Gene-level copy-number profile of tumor specimen TCGA-16-1060-01A from TCGA case TCGA-16-1060, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 70.7 years (25,813 days).
Specimen TCGA-16-1060-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.dd304b99-dbcd-463b-b6d0-5d17f7f83aed.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-16-1060-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6cb4cfce-187c-448a-b0cd-bbd134fa314f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 4,571; copy number 2: 53,222; copy number 3: 1,944; copy number 5: 18; copy number 14: 5; copy number 35: 15; copy number 39: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-16-1060-01): tumor purity 0.71, ploidy 1.92, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,278,050–22,214,672, 37 genes: IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 45 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:27,361,591–27,662,883, 8 genes, copy number 5 (within-gene range 5–26): AC004009.1, AC004009.3, AC004009.2, EIF4HP1, PSMC1P2, AC073150.1, HIBADH, AC007130.1.
- chr7:44,606,572–44,920,329, 10 genes, copy number 5 (within-gene range 2–5): OGDH, ZMIZ2, AC013436.1, PPIA, H2AZ2, LINC01952, PURB, MIR4657, AC004854.2, AC004854.1.
- chr7:53,776,136–55,572,988, 27 genes, copy number 14–39 (within-gene range 2–39): RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1.

Autosomal genes at a single copy (total copy number 1): 4,571. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
